Gene-level copy-number profile of tumor specimen HCM-WCMC-0950-C67-01A from HCMI case HCM-WCMC-0950-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma, non-invasive; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 63.0 years (23,007 days).
Specimen HCM-WCMC-0950-C67-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a69aedf5-e155-499a-a977-f7f90334fdd3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0950-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/80b12b08-0d1f-44db-aa94-64554437e334

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 7,624; copy number 2: 43,494; copy number 3: 7,763; copy number 4: 20; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,707,800–42,714,539, 1 gene: BX664718.1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:44,133,610–44,210,114, 1 gene, copy number 5 (within-gene range 2–5): GATD3A.

Autosomal genes at a single copy (total copy number 1): 4,778. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
